CCDI case PBBXME — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/33a4dfb8-4e69-4bc0-b83f-99fae88c2abf

Demographics
Sex at birth: male; Race: american indian or alaska native; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 19.9 years (7,258 days).

Biospecimens (3 samples)
- Sample 0DJVP4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJVPF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJVPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
